Gene-level copy-number profile of tumor specimen TCGA-13-1511-01A from TCGA case TCGA-13-1511, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 52.7 years (19,258 days).
Specimen TCGA-13-1511-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.0e7ef489-ce94-4404-8506-31d4b6cd02b9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1511-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9fc13d58-ef51-4023-8cb9-fbd9007626ee

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,036; copy number 2: 38,828; copy number 3: 8,887; copy number 4: 1,633; copy number 5: 151; copy number 6: 162; copy number 7: 21; copy number 8: 30; copy number 9: 32; copy number 11: 5; copy number 17: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-1511-01A-01D-0472-01): tumor purity 0.89, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 420 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:28,457,145–28,644,142, 1 gene, copy number 6 (within-gene range 4–6): PLB1.
- chr2:28,633,282–29,921,586, 19 genes, copy number 5–6 (within-gene range 3–6): AC074011.1, RNA5SP89, AC092164.1, PPP1CB, SPDYA, AC097724.1, TRMT61B, WDR43, SNORD92, SNORD53, Y_RNA, SNORD53B, TOGARAM2, Y_RNA, PCARE, AC105398.1, CLIP4, ALK, AC074096.1.
- chr2:163,743,913–168,247,595, 40 genes, copy number 5 (within-gene range 3–5): AC016766.1, PRPS1P1, CYP2C56P, GRB14, AC107075.1, COBLL1, AC019181.1, SNORA70F, AC019197.1, RNA5SP110, RNA5SP111, SLC38A11, SCN3A, SCN2A, MAPRE1P3, AC011303.1, CSRNP3, GALNT3, AC009495.3, AC009495.1, AC009495.2, TTC21B, TTC21B-AS1, SCN1A-AS1, SCN1A, Y_RNA, RN7SKP152, SCN9A, SCN7A, AC074101.1, XIRP2, AC092601.1, XIRP2-AS1, AC073050.1, RNU7-148P, CTAGE14P, B3GALT1-AS1, B3GALT1, STK39, PHF5GP.
- chr3:162,601,627–164,171,556, 8 genes, copy number 6: AC128716.1, AC128685.1, LINC01192, RPS6P4, AC079910.1, RNU7-82P, AC084017.1, MIR1263.
- chr3:167,065,831–170,454,733, 61 genes, copy number 8–11 (broad region; genes not listed).
- chr3:170,423,103–170,423,162, 1 gene, copy number 9: MIR6828.
- chr3:179,562,886–180,037,053, 13 genes, copy number 5 (within-gene range 3–5): ACTL6A, AC090425.3, AC090425.2, MRPL47, NDUFB5, AC090425.1, H3P13, USP13, PEX5L, AC007687.1, PEX5L-AS1, PEX5L-AS2, AC092939.1.
- chr5:23,262,159–23,528,093, 6 genes, copy number 6: AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1.
- chr8:107,899,316–113,616,958, 50 genes, copy number 5–8 (within-gene range 4–8): RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1.
- chr8:124,811,042–125,091,819, 12 genes, copy number 5 (within-gene range 4–5): AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1.
- chr8:127,578,473–127,742,951, 4 genes, copy number 6: AC104370.1, AC108925.1, CASC11, MYC.
- chr11:118,510,273–118,791,164, 16 genes, copy number 5 (within-gene range 3–5): AP001267.3, TTC36, TMEM25, IFT46, RPL5P30, ARCN1, RNU6-1157P, PHLDB1, AP000941.1, MIR6716, TREH, TREHP1, AP002954.1, RNU6-376P, AP002954.2, DDX6.
- chr12:71,007,773–72,186,618, 21 genes, copy number 5: AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1.
- chr12:72,249,964–72,276,954, 1 gene, copy number 5: TRHDE-AS1.
- chr12:100,357,074–100,628,288, 5 genes, copy number 6 (within-gene range 4–6): SLC17A8, NR1H4, AC010200.1, GAS2L3, PIGAP1.
- chr16:11,547,722–11,828,845, 8 genes, copy number 6 (within-gene range 3–6): LITAF, SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4.
- chr19:30,553,956–30,558,058, 1 gene, copy number 5: AC011504.1.
- chr20:61,252,261–62,841,159, 53 genes, copy number 6 (within-gene range 3–6): CDH4, AL365229.1, BX640515.1, AL160412.1, AL162457.1, AL162457.2, TAF4, MIR1257, AL137077.1, MIR3195, AL137077.2, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2, LINC00659, MRGBP, OGFR-AS1, OGFR, COL9A3.
- chr22:29,073,035–31,207,019, 100 genes, copy number 6–17 (within-gene range 2–17) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,893. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
